Surgical pathology report (de-identified scan), TCGA case TCGA-MI-A75E, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MI-A75E-01A (Primary Tumor).

[page 1 of 2]
[illegible]

ICD-O-3
Carcinoma, hepatocellular NOS
Site Liver 8170/3
C22.0
JW 8/13/13

SURGICAL PATHOLOGY

Accession No.

Date obtained:

BRIEF CLINICAL HISTORY:

OPERATIVE FINDINGS:

Surgeon/physician:

Accession No.

- SPECIMEN TYPE: LIVER SEGMENT, EN BLOC RESECTION.
- LATERALITY: LEFT LATERAL.
- TUMOR SITE: LEFT LATERAL

[page 2 of 2]
- TUMOR CONFIGURATION: SINGLE FOCUS.
- TUMOR SIZE: 4.3 CM IN GREATEST DIMENSION.
- HISTOLOGIC TYPE: HEPATOCELLULAR CAARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED (G2).
- MARGINS
- HEPATIC: NEGATIVE FOR TUMOR (3 CM FROM TUMOR).
- LYMPHO-VASCULAR INVASION: IDENTIFIED.
- INVASION THROUGH THE CAPSULE AND VISCERAL PERITONEUM INTO ADJACENT ADHERED OMENTUM WITH HEMATOMA AND ORGANIZATTION.

PATHOLOGIC STAGING (pTN):

- PRIMARY TUMOR: pT4 DUE TO VISCERAL PERITONEUM INVASION.

ADDITIONAL DIAGNOSES:

- CAPSULAR FIBROSIS WITH ORGANIZING HEMATOMA AND ADHESIONS EXTENDING TO ATTACHED OMENTUM (SEE ABOVE).
- CHRONIC HEPATITIS, GRADE 3, STAGE 2.

COMMENT: THE PREVIOUS BIOPSY WAS CORRELATED. THE TUMOR PERFORATES THE CAPSULE AND THE INVASION IS NOT A FEW CELL GROUPS BUT IS MEASURES AT LEAST 3 mm IN SIZE. THE TUMOR IS NOT SEEN AT THE INKED AREAS OF THE ATTACHED OMENTUM.

WAS NOTIFIED OF THE GROSS LIVER PARENCHYMAL MARGINS AT THE TIME OF THE RESECTION.

Signed

Source: NCI Genomic Data Commons file 499519a4-a156-4718-b969-4f5e38ab3003 (TCGA-MI-A75E.F88435AB-695B-4481-BE6C-93FEE7954465.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).